Gene-level copy-number profile of tumor specimen TCGA-ZD-A8I3-01A from TCGA case TCGA-ZD-A8I3, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 73.2 years (26,754 days).
Specimen TCGA-ZD-A8I3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CHOL.2bb39c53-bb3f-49af-bf8a-41994a1e5287.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZD-A8I3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b915c1a0-828c-49cc-b1d8-d7f856e955b0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 12,275; copy number 2: 47,433; copy number 17: 76; copy number 18: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZD-A8I3-01A-11D-A416-01): tumor purity 0.74, ploidy 1.82, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 38 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:68,460,731–68,615,334, 1 gene, copy number 18 (within-gene range 2–18): PPP6R3.
- chr11:68,612,899–69,819,416, 34 genes, copy number 18: AP003096.1, GAL, TESMIN, CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3.
- chr11:70,603,304–70,647,562, 3 genes, copy number 17: AP001271.2, SHANK2-AS1, SHANK2-AS2.

Autosomal genes at a single copy (total copy number 1): 12,267. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
